FM case AD2787 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/c1f9934b-cfb5-40ad-a15b-fafa452abb1d

Male, 46.9 years: diagnosis not reported by GDC; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
